Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3675, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3675-01A (Primary Tumor).

Diagnosis:

Ileocolic resection material includes a centrally ulcerated, moderately differentiated adenocarcinoma of the colorectal type in the region of the right flexure, with a maximum diameter of 4.5 cm with incipient infiltration of the pericolic fatty tissue (max. infiltration depth in fatty tissue less than 1 mm in the histological section). Tumor-free regional lymph nodes. Tumor-free resection margins of small intestine and colon. Three tubular colon mucosa adenomas with mild to moderate dysplasia (synonym: low-grade intraepithelial neoplasia).

Tumor stage: pT3 pN0 (0/24) pMX; G2, L0, V0, R0

Source: NCI Genomic Data Commons file cbffd865-e74d-4355-8d6a-9af293675bca (TCGA-AA-3675.F862FEA6-B8E7-4FAA-8E07-30E72608CD2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).